Somatic mutation profile of tumor specimen TCGA-S9-A7J2-01A (aliquot TCGA-S9-A7J2-01A-11D-A34A-08) from TCGA case TCGA-S9-A7J2, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 25.6 years (9,345 days).
Specimen TCGA-S9-A7J2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea5f5850-c18f-4884-ab6f-11d6ab9c5589.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7J2-10A (Blood Derived Normal), aliquot TCGA-S9-A7J2-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42193746-f1b4-4e41-b28d-0fb71ad804f3

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Frame Shift Del 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR1A | c.247_251del p.F83Hfs*6 | Frame Shift Del (DEL) | VAF 7/73 reads (10%) | catalogued as rs786204187; ClinVar: pathogenic; called by mutect2, pindel
- CIC | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 34/39 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157030312, COSV50547633; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 51/112 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AGAP1 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.151); catalogued as rs367742479; called by muse, mutect2
- CADPS | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs781371846, COSV51904713; called by muse, mutect2, varscan2
- HMGCS2 | c.600T>A p.Y200* | Nonsense Mutation (SNP) | VAF 3/27 reads (11%) | catalogued as COSV101024680; called by muse, mutect2
- RNF214 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1344664918, COSV56117761, COSV56121053; called by muse, mutect2, varscan2
- BCORL1 | c.3537del p.K1179Nfs*43 | Frame Shift Del (DEL) | VAF 13/16 reads (81%) | called by mutect2, varscan2
- COL2A1 | c.1353G>A p.P451= | Silent (SNP) | VAF 44/94 reads (47%) | catalogued as rs560149744, COSV61535859; called by muse, mutect2, varscan2
- EDN1 | c.537G>A p.S179= | Silent (SNP) | VAF 12/184 reads (7%) | catalogued as rs747564135, COSV101040276; called by muse, mutect2
- MIR508 | n.102C>T | RNA (SNP) | VAF 22/24 reads (92%) | catalogued as rs376885438; called by muse, mutect2, varscan2
